Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4XC, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4XC-01A (Primary Tumor).

[page 1 of 2]
Proce

Recei

Repor

Final Diagnosis:

A, B. Brain, left temporal mass, CUSA and resection: Diffusely infiltrative glioma with features most consistent with low grade oligoastrocytoma (WHO grade II). See comment.

Comment: This is an unusual case since the patient has a separate lesion in the opposite hemisphere (right frontal), which has features quite similar on imaging and on biopsy demonstrated morphologic features of an anaplastic astrocytoma (WHO grade III). The morphologic features of the 2 tumors will be compared upon resection of the right frontal tumor, which is scheduled for

Immunohistochemical stains were performed on paraffin-embedded tissue using antibodies to GFAP, MIB-1 and p53. GFAP is positive in tumor cells, which have scant cytoplasm. p53 is variably expressed in over 50% of tumor cells. MIB-1 labeling index varies from low to moderate. The findings support the above diagnosis.

ADDENDA:

Fluorescence in situ hybridization (FISH) studies for 1p19q deletion have been ordered on paraffin sections and will be performed by the

1CD-0-3

Oligoastrocytoma 9382/3

Site: Brain, temporal lobe C71.2

fw
10/24/12

[page 2 of 2]
Preliminary Frozen Section Consultation:

A. Brain, left temporal mass, smears: Glioma, consistent with recurrent grade 3 astrocytoma. Hold over for definitive grading.

Intraoperative cytologic smear(s) and frozen section histologic interpretation performed by:
M.D.

Gross Description:

A. Received fresh labeled "left temporal brain mass" is a 20.7 gram, 5.2 x 3.7 x 1.7 cm portion of brain. Smears prepared. Representative sections are submitted. Grossed by

B. Received fresh within a CUSA trap labeled "CUSA specimen trap - left temporal brain mass" is a 5.0 x 4.3 x 1.0 cm aggregate of brain. All submitted for permanent sections only. Grossed by

Block Summary:

Part A: Left temporal brain mass

- 1 Lt temporal brain
- 2 Lt temporal brain
- 3 Lt temporal brain
- 4 Lt temporal brain
- 5 Lt temporal brain

Part B: CUSA specimen trap-Left temporal brain mass

- 1 Cusa Lt temporal brain
- 2 Cusa Lt temporal brain
- 3 Cusa Lt temporal brain
- 4 Cusa Lt temporal brain

END OF REPORT

Page 2 of 2

diPFA Discrepancy		☒
Prone Malignancy History		☒

Source: NCI Genomic Data Commons file 5fde5186-4c35-408a-97f8-31cde89635e1 (TCGA-DB-A4XC.26BC05CE-7A4F-4E5C-84A5-7BA6EC72505D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).